Somatic mutation profile of tumor specimen C3L-02856-01 (aliquot CPT0172010006) from CPTAC case C3L-02856, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 89.6 years (32,731 days).
Specimen C3L-02856-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d724efe-40f0-4eee-8fbf-6e2af79ef3d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02856-31 (Blood Derived Normal), aliquot CPT0167470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fb91554-ac38-4d04-904a-34a3c52fb39f

The open-access MAF lists 104 somatic variants for this specimen: 73 protein-altering or splice-affecting, 25 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 25, Frame Shift Del 7, Nonsense Mutation 5, 5'Flank 2, Frame Shift Ins 1, 3'Flank 1, RNA 1, 5'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.333C>A p.S111R | Missense Mutation (SNP) | VAF 64/521 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as CM951281, COSV56542656, COSV56544837, COSV56553040, COSV56574177; called by muse, mutect2, varscan2
- AC100868.1 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as rs372255074; called by muse, mutect2
- ADGRL4 | c.1886C>G p.T629S | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV100875958, COSV66065106; called by muse, mutect2, varscan2
- ANGPTL4 | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 40/482 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.179); catalogued as rs759967878; called by muse, mutect2
- ATP1A2 | c.1129G>T p.G377C | Missense Mutation (SNP) | VAF 144/809 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63406084; called by muse, mutect2, varscan2
- BAP1 | c.280C>G p.H94D | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56238285; called by muse, mutect2, varscan2
- CD2AP | c.861A>T p.E287D | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147947745; called by muse, varscan2
- CSNK1A1L | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as rs1317209838, COSV65789807; called by muse, mutect2, varscan2
- DEGS1 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as rs747376061, COSV100083352; called by muse, mutect2, varscan2
- HTATIP2 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 42/478 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1338723434, COSV58173979; called by muse, mutect2
- IGSF11 | c.478G>A p.D160N (on ENST00000393775 / NM_001015887.3; = p.D159N on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.983); catalogued as rs767516463, COSV61178655; called by muse, mutect2, varscan2
- LFNG | c.919C>T p.R307C (on ENST00000222725 / NM_001040167.2; = p.R178C on NM_002304.2) | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs771328560; called by muse, mutect2, varscan2
- LRRC8D | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs139352797; called by muse, mutect2
- MYO18B | c.7630G>A p.E2544K | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as rs760339139, COSV59130770; called by muse, mutect2, varscan2
- PDE4D | c.649C>G p.H217D (on ENST00000340635 / NM_001104631.2; = p.H81D on NM_006203.4) | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV58986713; called by muse, mutect2
- PLEKHG5 | c.1489C>T p.R497W (on ENST00000400915 / NM_001042663.3; = p.R460W on NM_020631.6) | Missense Mutation (SNP) | VAF 76/672 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1228766995; called by muse, mutect2, varscan2
- PRLR | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as rs544936476; called by muse, mutect2, varscan2
- PROX1 | c.204T>A p.N68K | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs745794343; called by muse, mutect2, varscan2
- RAB34 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 42/389 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs762752582; called by muse, mutect2, varscan2
- RBM15 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100873450; called by muse, mutect2
- SEL1L | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1481268940, COSV100378062, COSV60921222, COSV60923601; called by muse, mutect2
- SEMA3E | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 22/228 reads (10%) | catalogued as rs1401325086; called by muse, mutect2
- SLC10A5 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs754413209; called by mutect2, varscan2
- ZNF395 | c.1438del p.R480Efs*51 | Frame Shift Del (DEL) | VAF 40/346 reads (12%) | catalogued as COSV60429135, COSV60429732; called by mutect2, pindel, varscan2
- ABCB10 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ALG11 | c.594T>A p.H198Q | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD36 | c.3852G>A p.M1284I | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.033); called by muse, mutect2
- ARSA | c.692del p.H231Pfs*23 | Frame Shift Del (DEL) | VAF 19/143 reads (13%) | called by mutect2, pindel, varscan2
- ATG7 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- ATP7B | c.1579A>C p.K527Q | Missense Mutation (SNP) | VAF 42/467 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- BDH2 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- C20orf204 | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.808); called by muse, mutect2
- CARMIL2 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- CEBPD | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.052); called by muse, mutect2
- CELSR1 | c.1709T>C p.F570S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNKSR2 | c.210del p.D71Tfs*6 | Frame Shift Del (DEL) | VAF 28/173 reads (16%) | called by mutect2, pindel, varscan2
- DDX17 | c.1855T>C p.Y619H | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- EIF2AK4 | c.1805del p.G602Efs*17 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- FAM3A | c.386-7C>A | Splice Region (SNP) | VAF 29/306 reads (9%) | called by muse, mutect2
- GOLGA8Q | c.1136A>C p.N379T | Missense Mutation (SNP) | VAF 75/708 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- HMCN1 | c.16771G>A p.V5591M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- IL21 | c.28A>T p.R10W | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.077); called by muse, mutect2
- KLHL21 | c.143dup p.A49Gfs*59 | Frame Shift Ins (INS) | VAF 40/361 reads (11%) | called by mutect2, pindel, varscan2
- LAMA3 | c.6937G>T p.V2313L (on ENST00000313654 / NM_198129.4; = p.V704L on NM_000227.6) | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- LGALS12 | c.458T>G p.I153S | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- MAPK8IP3 | c.3007C>A p.L1003M | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MBD5 | c.2295C>A p.N765K | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2
- MFSD12 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 37/348 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- MFSD8 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- MSL2 | c.1027_1033del p.S343Qfs*28 | Frame Shift Del (DEL) | VAF 37/213 reads (17%) | called by mutect2, pindel, varscan2
- MYEF2 | c.136A>G p.S46G | Missense Mutation (SNP) | VAF 58/596 reads (10%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- NCKAP5L | c.1752C>A p.Y584* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- NKAIN2 | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 27/227 reads (12%) | called by muse, mutect2, varscan2
- NOX5 | c.431A>G p.D144G | Missense Mutation (SNP) | VAF 44/506 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- OGA | c.435T>G p.F145L | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2
- PAN3 | c.1390A>C p.I464L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2
- PIK3R2 | c.652_658del p.R218Sfs*121 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel, varscan2
- PLEKHA2 | c.1199G>T p.R400I | Missense Mutation (SNP) | VAF 45/439 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- PPIL4 | c.1320C>A p.N440K | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- PPIL4 | c.1318A>T p.N440Y | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2
- PRAMEF10 | c.1233G>T p.L411F | Missense Mutation (SNP) | VAF 32/590 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.545); called by muse, mutect2
- PTPN20 | c.814T>A p.S272T | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- REXO4 | c.625_628delinsAG p.G209Sfs*40 | Frame Shift Del (DEL) | VAF 32/375 reads (9%) | called by pindel, varscan2*
- SEC23IP | c.2809G>T p.G937* | Nonsense Mutation (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- SERPINB9 | c.992C>A p.A331E | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SORCS2 | c.644G>A p.R215K | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TP53AIP1 | c.110A>T p.N37I | Missense Mutation (SNP) | VAF 35/363 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- UAP1L1 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ULK1 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC13B | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 51/493 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); called by muse, mutect2
- USP34 | c.8095C>G p.Q2699E | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2
- VGLL3 | c.621G>T p.W207C | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- ZNF469 | c.4462C>T p.P1488S (on ENST00000437464; = p.P1516S on NM_001367624.2) | Missense Mutation (SNP) | VAF 90/964 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); called by muse, mutect2
- ADRA2A | c.894C>A p.A298= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- AHCTF1 | c.3126C>T p.V1042= (on ENST00000366508; = p.V1016= on NM_015446.5) | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- BAP1 | c.279T>A p.T93= | Silent (SNP) | VAF 43/396 reads (11%) | called by muse, mutect2, varscan2
- CCL5 | c.234G>A p.K78= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as rs1184686894; called by muse, mutect2
- CEP57 | c.651C>A p.L217= | Silent (SNP) | VAF 28/215 reads (13%) | catalogued as rs200137467, COSV57689300; called by muse, mutect2, varscan2
- CGB5 | c.483G>T p.P161= | Silent (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- CLPX | c.1080A>T p.V360= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- DNAH17 | c.660G>A p.L220= | Silent (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- DNHD1 | c.10830G>A p.E3610= | Silent (SNP) | VAF 21/224 reads (9%) | called by muse, mutect2
- ELOA | c.744C>T p.L248= | Silent (SNP) | VAF 38/327 reads (12%) | catalogued as rs772281863; called by muse, mutect2, varscan2
- EPS8L1 | c.1134C>A p.A378= (on ENST00000201647 / NM_133180.3; = p.A251= on NM_017729.3) | Silent (SNP) | VAF 22/310 reads (7%) | called by muse, mutect2
- FAM234A | c.1254G>A p.G418= | Silent (SNP) | VAF 26/208 reads (13%) | called by muse, mutect2, varscan2
- FLG | c.3510G>C p.G1170= | Silent (SNP) | VAF 52/682 reads (8%) | catalogued as COSV64242123; called by muse, mutect2
- HAS2 | c.510C>T p.H170= | Silent (SNP) | VAF 30/386 reads (8%) | catalogued as rs373683528; called by muse, mutect2
- JMJD1C | c.6393A>G p.V2131= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV100550178; called by muse, mutect2, varscan2
- KRTAP19-1 | c.147C>A p.G49= | Silent (SNP) | VAF 82/652 reads (13%) | called by muse, mutect2, varscan2
- MPV17 | c.99C>T p.I33= | Silent (SNP) | VAF 63/671 reads (9%) | called by muse, mutect2
- MSX2 | c.81G>A p.G27= | Silent (SNP) | VAF 39/399 reads (10%) | called by muse, mutect2, varscan2
- MUC2 | c.2430C>G p.G810= | Silent (SNP) | VAF 47/430 reads (11%) | called by muse, mutect2, varscan2
- NAALAD2 | c.456T>C p.N152= | Silent (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- PTPRB | c.4566G>A p.R1522= | Silent (SNP) | VAF 32/266 reads (12%) | called by muse, varscan2
- SAAL1 | c.1272G>A p.Q424= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs934632535; called by muse, mutect2, varscan2
- SERPINB9 | c.993A>G p.A331= | Silent (SNP) | VAF 28/335 reads (8%) | catalogued as COSV101046696; called by muse, mutect2
- UBR1 | c.1405T>C p.L469= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as rs146690613; called by muse, mutect2
- URB1 | c.6750G>A p.P2250= | Silent (SNP) | VAF 24/313 reads (8%) | catalogued as rs894613595; called by muse, mutect2
- EIF4G2 | chr11:10808264 A>G | 5'Flank (SNP) | VAF 12/110 reads (11%) | catalogued as rs1388968595; called by muse, mutect2
- ITGA8 | c.-1G>A | 5'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, varscan2
- PCCB | chr3:136333432 G>A | 3'Flank (SNP) | VAF 22/180 reads (12%) | called by muse, mutect2, varscan2
- SLC6A8 | c.778-59G>T | Intron (SNP) | VAF 48/522 reads (9%) | called by muse, mutect2
- SPATA31C2 | n.920T>G | RNA (SNP) | VAF 57/599 reads (10%) | called by muse, mutect2
- UBE2Q2L | chr15:84172522 T>A | 5'Flank (SNP) | VAF 27/377 reads (7%) | called by muse, mutect2
